Gene-level copy-number profile of tumor specimen TCGA-D3-A2JA-06A from TCGA case TCGA-D3-A2JA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 70.9 years (25,907 days).
Specimen TCGA-D3-A2JA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.0fb005c1-aac5-47df-998d-d87b3712b60b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A2JA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/184c9067-2fb0-40a6-98c9-f1759fbeb943

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4,376; copy number 2: 30,199; copy number 3: 14,056; copy number 4: 10,538; copy number 5: 75; copy number 7: 120; copy number 9: 56; copy number 10: 230; copy number 11: 151; copy number 13: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A2JA-06A-11D-A194-01): tumor purity 0.5, ploidy 2.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 641 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:48,809,340–49,419,013, 1 gene, copy number 5 (within-gene range 4–5): AC009975.1.
- chr2:48,962,157–54,383,742, 49 genes, copy number 5 (within-gene range 4–5): FSHR, MIR548BA, AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3, AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73.
- chr2:106,801,600–109,504,634, 47 genes, copy number 5–11: ST6GAL2, ST6GAL2-IT1, AC016994.1, AC005040.2, PPP1R2P5, AC005040.1, LINC01789, AC096669.1, LINC01885, LINC01886, AC064869.1, GACAT1, RGPD4-AS1, RGPD4, AC009963.2, AC009963.1, RPL22P8, SRSF3P5, SLC5A7, LINC01593, ACTP1, LINC01594, SETD6P1, SULT1C3, WASF1P1, SULT1C2, SULT1C2P2, SULT1C2P1, GMCL1P2, SULT1C4, SMIM12P1, GCC2, GCC2-AS1, LIMS1, LIMS1-AS1, AC010095.1, RPL10P5, RANBP2, CCDC138, RPL39P16, EDAR, Metazoa_SRP, SH3RF3-AS1, SH3RF3, MIR4265, SNRPGP9, MIR4266.
- chr2:113,325,372–129,071,725, 201 genes, copy number 10 (broad region; genes not listed).
- chr2:131,035,092–132,406,858, 77 genes, copy number 5–11 (broad region; genes not listed).
- chr2:132,488,554–132,523,936, 2 genes, copy number 11: YBX1P7, RN7SKP103.
- chr2:138,669,157–145,931,146, 72 genes, copy number 11–13 (broad region; genes not listed).
- chr2:156,305,108–157,049,716, 8 genes, copy number 11: AC074099.1, NR4A2, GPD2, LINC01958, RPLP0P7, AC096589.2, AC096589.1, AC108057.1.
- chr2:161,992,245–164,843,679, 24 genes, copy number 11 (within-gene range 4–11): DPP4, DPP4-DT, TIMM8AP1, EIF3EP2, AC008063.1, GCG, AC007750.1, FAP, IFIH1, GCA, KCNH7, RNA5SP109, KCNH7-AS1, RPL7P61, RNU6-627P, FIGN, AC016766.1, PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F.
- chr2:171,783,405–172,370,401, 10 genes, copy number 11 (within-gene range 4–11): SLC25A12, RNU6-182P, HAT1, METAP1D, DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.3, AC104088.2.
- chr2:198,299,276–198,375,490, 1 gene, copy number 9 (within-gene range 4–9): LINC01923.
- chr2:211,375,717–212,538,841, 1 gene, copy number 10 (within-gene range 4–10): ERBB4.
- chr2:212,426,263–215,310,947, 28 genes, copy number 10: MIR548F2, AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2, IKZF2, AC079610.1, LINC01953, AC079610.2, SPAG16-DT, SPAG16, MIR4438, AC068051.1, RPL5P8, VWC2L, VWC2L-IT1, ENSAP3, BARD1, SNHG31, SNORA70I, RPL10P6, ABCA12, AC072062.1, AC092844.1, LINC02862.
- chr8:38,510,834–43,674,591, 120 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,016. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
